Gene-level copy-number profile of tumor specimen C3N-06996-01 from CPTAC case C3N-06996, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.0 years (21,911 days).
Specimen C3N-06996-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1b730e7c-315f-4dee-b4ac-2c58dce163a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-06996-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/a9aac5ef-599e-481b-936a-a6456e87d4f7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 813; copy number 2: 10,722; copy number 3: 25,675; copy number 4: 15,597; copy number 5: 5,763; copy number 6: 222; copy number 8: 28; copy number 10: 94.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,951,242–21,951,323, 1 gene: MIR5701-3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 122 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:3,385,930–5,096,374, 94 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr17:11,157,455–12,215,267, 14 genes, copy number 10: RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.
- chr17:13,494,032–13,601,929, 2 genes, copy number 8 (within-gene range 4–8): HS3ST3A1, MIR548H3.
- chr17:15,266,848–15,311,760, 1 gene, copy number 8 (within-gene range 2–8): AC005703.6.
- chr17:15,303,811–15,563,595, 11 genes, copy number 8: TEKT3, RNU6-799P, AC005703.4, AC005703.3, RN7SL792P, CDRT4, TVP23C-CDRT4, RPL9P2, TVP23C, PPIAP53, AC005838.2.

Autosomal genes at a single copy (total copy number 1): 301. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
